Gene-level copy-number profile of tumor specimen TCGA-BF-AAP6-01A from TCGA case TCGA-BF-AAP6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 55.8 years (20,384 days).
Specimen TCGA-BF-AAP6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.11317b3e-c521-43df-9580-6ab47c111a97.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BF-AAP6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d70a4ac9-393e-4ca9-901e-663675d82ee1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,618; copy number 2: 35,941; copy number 3: 9,605; copy number 4: 2,628; copy number 5: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BF-AAP6-01A-11D-A400-01): tumor purity 0.86, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:3,357,264–4,866,311, 12 genes, copy number 5 (within-gene range 1–5): LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1.
- chr5:8,525,144–8,572,206, 2 genes, copy number 5: AC091953.1, AC091953.3.

Autosomal genes at a single copy (total copy number 1): 9,238. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
